Somatic mutation profile of tumor specimen TCGA-29-1697-01A (aliquot TCGA-29-1697-01A-01W-0633-09) from TCGA case TCGA-29-1697, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 62.8 years (22,933 days).
Specimen TCGA-29-1697-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7387513e-4989-4289-be63-baa035e90ced.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-29-1697-10A (Blood Derived Normal), aliquot TCGA-29-1697-10A-01W-0633-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4d9aeff5-69d0-4f0d-95d8-c46c34b51333

The open-access MAF lists 35 somatic variants for this specimen: 25 protein-altering or splice-affecting, 9 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 19, Silent 9, Nonsense Mutation 2, Frame Shift Ins 2, Frame Shift Del 2, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CHD7 | c.4393C>T p.R1465* | Nonsense Mutation (SNP) | VAF 31/53 reads (58%) | catalogued as rs886040991, CD126766, CM060211, COSV71112190; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.712T>G p.C238G | Missense Mutation (SNP) | VAF 94/95 reads (99%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519981, CM025271, CM056070, COSV52699956, COSV52707471, COSV52711035, COSV52711932; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- APBB1 | c.800G>T p.G267V | Missense Mutation (SNP) | VAF 57/61 reads (93%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54977548, COSV54977799; called by muse, mutect2, varscan2
- CNOT2 | c.97G>T p.V33F | Missense Mutation (SNP) | VAF 86/184 reads (47%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.298); catalogued as COSV57503974; called by muse, mutect2, varscan2
- CNTNAP5 | c.3145G>T p.A1049S | Missense Mutation (SNP) | VAF 37/76 reads (49%) | SIFT tolerated (0.81); PolyPhen benign (0.174); catalogued as COSV70480392, COSV70487455; called by muse, mutect2, varscan2
- CYP11B2 | c.367C>T p.R123C | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.427); catalogued as rs745436748, COSV59996500; called by muse, mutect2, varscan2
- ERO1B | c.995A>C p.N332T | Missense Mutation (SNP) | VAF 80/177 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.643); catalogued as COSV51596090; called by muse, mutect2, varscan2
- FANCM | c.1756_1768del p.V586Lfs*80 | Frame Shift Del (DEL) | VAF 36/39 reads (92%) | catalogued as COSV57502616; called by mutect2, pindel, varscan2
- FMNL2 | c.2377G>T p.E793* | Nonsense Mutation (SNP) | VAF 23/72 reads (32%) | catalogued as COSV56497793; called by muse, mutect2, varscan2
- GPR89B | c.50T>C p.F17S | Missense Mutation (SNP) | VAF 58/146 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.299); catalogued as COSV58501880; called by muse, mutect2, varscan2
- HSPG2 | c.3202G>A p.D1068N | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1049233829, COSV65969005; called by muse, mutect2, varscan2
- IKBKB | c.1501A>C p.T501P | Missense Mutation (SNP) | VAF 10/227 reads (4%) | SIFT tolerated (0.12); PolyPhen benign (0.285); catalogued as COSV100645814; called by muse, mutect2
- INO80D | c.2102G>T p.G701V | Missense Mutation (SNP) | VAF 98/286 reads (34%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.049); catalogued as COSV68959344; called by muse, mutect2, varscan2
- KPNA1 | c.857A>G p.N286S | Missense Mutation (SNP) | VAF 55/109 reads (50%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.839); catalogued as rs1336879899, COSV60268505; called by muse, mutect2, varscan2
- NALCN | c.4139C>T p.T1380I | Missense Mutation (SNP) | VAF 44/49 reads (90%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as COSV51944342; called by muse, mutect2, varscan2
- PSMC4 | c.435dup p.E146Rfs*97 | Frame Shift Ins (INS) | VAF 4/35 reads (11%) | catalogued as rs747871663; called by pindel, varscan2
- SCAPER | c.1684C>T p.R562C | Missense Mutation (SNP) | VAF 44/47 reads (94%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV57743248; called by muse, mutect2, varscan2
- SETD3 | c.814C>G p.P272A | Missense Mutation (SNP) | VAF 8/130 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100075417; called by muse, mutect2
- SIMC1 | c.2354G>C p.R785T (on ENST00000443967 / NM_001308196.1; = p.R370T on NM_198567.5) | Missense Mutation (SNP) | VAF 4/84 reads (5%) | SIFT tolerated (0.17); PolyPhen benign (0.087); catalogued as COSV100231345; called by muse, mutect2
- SYCP1 | c.1251T>A p.S417R | Missense Mutation (SNP) | VAF 48/101 reads (48%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as COSV65698697; called by muse, mutect2, varscan2
- THOC7 | c.242A>T p.Y81F | Missense Mutation (SNP) | VAF 27/58 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55733732; called by muse, mutect2, varscan2
- TMEM260 | c.1749_1762del p.V584Nfs*14 | Frame Shift Del (DEL) | VAF 30/106 reads (28%) | catalogued as COSV55100527; called by mutect2, pindel, varscan2
- TP53TG5 | c.14C>T p.A5V | Missense Mutation (SNP) | VAF 48/356 reads (13%) | SIFT tolerated (0.3); PolyPhen benign (0.078); catalogued as COSV65577731; called by muse, varscan2
- TSNAX | c.182G>A p.R61Q | Missense Mutation (SNP) | VAF 62/116 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV64146527; called by muse, mutect2, varscan2
- AFDN | c.1580+1dup | Frame Shift Ins (INS) | VAF 94/142 reads (66%) | called by mutect2, pindel, varscan2
- C5 | c.3036G>A p.L1012= | Silent (SNP) | VAF 30/77 reads (39%) | catalogued as rs750189746, COSV56328967; called by muse, mutect2, varscan2
- CPAMD8 | c.1599C>T p.Y533= (on ENST00000651564; = p.Y486= on NM_015692.5) | Silent (SNP) | VAF 19/40 reads (48%) | catalogued as rs994174876, COSV52236075; called by muse, mutect2, varscan2
- ELAPOR1 | c.549G>C p.L183= | Silent (SNP) | VAF 39/160 reads (24%) | catalogued as COSV64045565; called by muse, mutect2, varscan2
- FGF14 | c.657G>A p.P219= | Silent (SNP) | VAF 78/83 reads (94%) | catalogued as rs777271756, COSV65946626; called by muse, mutect2, varscan2
- PNMA8B | c.81G>A p.P27= | Silent (SNP) | VAF 22/22 reads (100%) | catalogued as COSV66536759, COSV66537343; called by muse, mutect2, varscan2
- RAB11FIP5 | c.1659C>T p.S553= | Silent (SNP) | VAF 122/230 reads (53%) | catalogued as rs1384372825, COSV50251669; called by muse, mutect2, varscan2
- RYR1 | c.3865C>A p.R1289= | Silent (SNP) | VAF 19/37 reads (51%) | catalogued as COSV62090900, COSV62101258; called by muse, varscan2
- SLC17A1 | c.195G>C p.L65= | Silent (SNP) | VAF 133/144 reads (92%) | catalogued as COSV55079740, COSV99765826; called by muse, mutect2, varscan2
- TBC1D19 | c.1071T>C p.F357= | Silent (SNP) | VAF 68/69 reads (99%) | catalogued as COSV53518002; called by muse, mutect2, varscan2
- MIR524 | n.15C>G | RNA (SNP) | VAF 148/157 reads (94%) | called by muse, mutect2, varscan2
